Somatic mutation profile of tumor specimen 0DU9N1 from CCDI case PBCIJC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,318 days).
Specimen 0DU9N1: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5aabf48-49eb-4fee-ae69-aa99f9256abb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9N7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cee2b00-7aa9-49a5-b9eb-3f19f14ba265

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 236/559 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP2F1 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 53/799 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779982873, COSV104401981; called by muse, mutect2
- PDHA2 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 184/397 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV54783100; called by muse, mutect2, varscan2
- PLAAT5 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); catalogued as COSV57138155; called by muse, mutect2
- RNF5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 53/243 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs1263853389; called by muse, mutect2, varscan2
- ADHFE1 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- BMP5 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 20/611 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRMT10C | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 58/668 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2
- NWD2 | c.2652G>A p.S884= | Silent (SNP) | VAF 60/1282 reads (5%) | catalogued as rs150067567, COSV58753059; called by muse, mutect2
- PROM1 | c.462G>A p.L154= | Silent (SNP) | VAF 40/740 reads (5%) | called by muse, mutect2
- MED24 | c.2705-14C>G | Intron (SNP) | VAF 69/719 reads (10%) | catalogued as rs1489013696; called by muse, mutect2
